Gene-level copy-number profile of tumor specimen TCGA-FA-A6HN-01A from TCGA case TCGA-FA-A6HN, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 74.0 years (27,025 days).
Specimen TCGA-FA-A6HN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.4c31c45b-b980-4a49-9237-f3d65a216956.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FA-A6HN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e10ed2ed-7ba9-486b-a8bb-de870b667ee2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 2,694; copy number 2: 54,649; copy number 3: 2,021; copy number 4: 432.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FA-A6HN-01A-11D-A31W-01): tumor purity 0.41, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:50,664,903–50,807,629, 9 genes: AC007608.3, SNX20, NOD2, AC007728.3, AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168.
- chr16:50,856,614–50,879,278, 1 gene (within-gene range 0–1): AC025810.1.
- chr16:78,234,652–78,553,296, 7 genes: WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 683. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
